Somatic mutation profile of tumor specimen C3L-04033-01 (aliquot CPT0231350007) from CPTAC case C3L-04033, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 39.2 years (14,325 days).
Specimen C3L-04033-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48851932-8966-4d8c-94d4-add4aa7242a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04033-32 (Blood Derived Normal), aliquot CPT0231510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76645ca9-d727-4c68-baf0-c6ba9caf333b

The open-access MAF lists 54 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 9, Frame Shift Del 7, Intron 4, Nonsense Mutation 2, Splice Site 2, 3'UTR 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP2S1 | c.902T>A p.F301Y | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV59505908; called by muse, mutect2, varscan2
- HLA-DRA | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs765347014, COSV66622503; called by muse, mutect2
- KCNE4 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1233817939, COSV56055061; called by muse, mutect2, varscan2
- LAMC3 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs781114465; called by muse, mutect2, varscan2
- MYH14 | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as CM041811; called by muse, mutect2, varscan2
- NTM | c.309G>T p.Q103H | Missense Mutation (SNP) | VAF 32/423 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV66184864; called by muse, mutect2
- PCDHB2 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 28/886 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99167022; called by muse, mutect2
- RTN3 | c.400C>T p.Q134* (on ENST00000377819 / NM_001265589.2; = p.Q115* on NM_201428.3) | Nonsense Mutation (SNP) | VAF 70/192 reads (36%) | catalogued as COSV58028580; called by muse, mutect2, varscan2
- RYR2 | c.6965G>C p.R2322T | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100773073; called by muse, mutect2
- SOGA3 | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs1304070340, CM124428; called by muse, mutect2
- BAP1 | c.2062C>G p.L688V | Missense Mutation (SNP) | VAF 90/172 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, varscan2
- BCL9L | c.1991G>A p.G664D | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CNTNAP4 | c.650G>T p.S217I | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- CPQ | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- CRTC3 | c.356_362del p.D119Vfs*33 | Frame Shift Del (DEL) | VAF 29/61 reads (48%) | called by mutect2, pindel, varscan2
- DCAF12 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- FAT4 | c.10729_10735del p.E3577Lfs*29 | Frame Shift Del (DEL) | VAF 49/146 reads (34%) | called by mutect2, pindel, varscan2
- GFRA3 | c.1025-1G>C p.X342_splice | Splice Site (SNP) | VAF 69/178 reads (39%) | called by muse, mutect2, varscan2
- HDGFL2 | c.1853A>G p.E618G | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.07); called by muse, mutect2, varscan2
- HDLBP | c.2918del p.V973Afs*5 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- KCTD3 | c.1866C>A p.H622Q | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIDEAS | c.2163-1G>C p.X721_splice | Splice Site (SNP) | VAF 19/41 reads (46%) | called by muse, varscan2
- NUP88 | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- PARG | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 140/174 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PDE6A | c.452C>G p.A151G | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- PSAPL1 | c.997del p.T333Rfs*103 | Frame Shift Del (DEL) | VAF 61/215 reads (28%) | called by mutect2, pindel, varscan2
- RIF1 | c.1637C>G p.S546* | Nonsense Mutation (SNP) | VAF 80/282 reads (28%) | called by muse, varscan2
- RSU1 | c.137T>A p.V46D | Missense Mutation (SNP) | VAF 100/151 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- RTL9 | c.1393_1394del p.A465Tfs*56 | Frame Shift Del (DEL) | VAF 74/129 reads (57%) | called by mutect2, pindel, varscan2
- SMG6 | c.2213A>G p.Y738C | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST18 | c.2399T>C p.V800A | Missense Mutation (SNP) | VAF 12/404 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.118); called by muse, mutect2
- ST8SIA1 | c.794del p.S265Ifs*16 | Frame Shift Del (DEL) | VAF 67/248 reads (27%) | called by mutect2, pindel, varscan2
- TEAD3 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- TTLL6 | c.1922C>A p.S641Y (on ENST00000393382 / NM_001130918.3; = p.S334Y on NM_173623.3) | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- UQCRQ | c.176T>A p.I59N | Missense Mutation (SNP) | VAF 102/289 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- WDR44 | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 72/95 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ZNF561 | c.1247_1250del p.S416Kfs*48 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- ZNF91 | c.2665A>G p.K889E | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- ACKR1 | c.957G>T p.L319= | Silent (SNP) | VAF 14/216 reads (6%) | catalogued as COSV63672530; called by muse, mutect2
- GCSAML | c.261T>C p.D87= | Silent (SNP) | VAF 95/469 reads (20%) | catalogued as rs1270099340; called by muse, mutect2, varscan2
- GLRA1 | c.1122C>G p.A374= (on ENST00000455880 / NM_001146040.2; = p.A366= on NM_000171.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- KLHDC9 | c.1017C>T p.A339= | Silent (SNP) | VAF 37/145 reads (26%) | called by muse, mutect2, varscan2
- LTBP1 | c.4485C>T p.H1495= (on ENST00000404816 / NM_206943.4; = p.H1169= on NM_000627.4) | Silent (SNP) | VAF 106/152 reads (70%) | catalogued as rs1377963990; called by muse, mutect2, varscan2
- NLRP12 | c.1029G>A p.R343= | Silent (SNP) | VAF 66/501 reads (13%) | catalogued as COSV60756406; called by muse, mutect2, varscan2
- PLCB3 | c.3396A>T p.S1132= | Silent (SNP) | VAF 93/246 reads (38%) | called by muse, mutect2, varscan2
- RING1 | c.1032T>C p.G344= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- TNS1 | c.4104C>T p.T1368= | Silent (SNP) | VAF 58/200 reads (29%) | catalogued as rs555472636; called by muse, mutect2, varscan2
- AC092329.3 | c.-211-445C>T | Intron (SNP) | VAF 84/319 reads (26%) | called by muse, mutect2, varscan2
- ADAM11 | c.*406C>T | 3'UTR (SNP) | VAF 110/340 reads (32%) | called by muse, mutect2, varscan2
- ADAM11 | c.*407C>A | 3'UTR (SNP) | VAF 108/335 reads (32%) | called by muse, mutect2, varscan2
- CCDC57 | c.2564-11656G>C | Intron (SNP) | VAF 94/265 reads (35%) | called by muse, mutect2, varscan2
- MIR656 | n.47T>C | RNA (SNP) | VAF 28/788 reads (4%) | called by muse, mutect2
- OGG1 | c.138-44_138-36del | Intron (DEL) | VAF 113/357 reads (32%) | called by mutect2, pindel, varscan2
- RLN1 | c.211+236G>T | Intron (SNP) | VAF 33/205 reads (16%) | called by muse, mutect2, varscan2
